Surgical pathology report (de-identified scan), TCGA case TCGA-D5-5541, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-5541-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Material: Multiple organ resection – segment of the large intestine

Unit in charge:

TCGA – D5 – 5541

Material collected on: Material received on:

Clinical diagnosis: Sigmoid colon carcinoma – sigmoidektomia.

Examination performed on:

Macroscopic description:

13.3 cm length of the large intestine with a segment of the mesenterium sized 15 x 10 x 2.5cm. Cauliflower-shaped tumour sized 5.9 x 4.9 x 1.3 cm in the mucosa. The lesion surrounding 95% of the intestine circumference, located 3.6cm from one of the incision lines, and 6.2 cm from the opposite one.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa telae adiposae pericolicae. Intestine ends free of neoplastic lesions. Metastases carcinomatosae in lymphonodo (No I / VIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli.
Metastases carcinomatosae in lymphonodo (No I / VIII).
(G2, Dukes C, Astler-Coller C2, pT3, pN1).

TUBULOAPILLARY ADENOCARCINOMA OF THE COLON
METASTATIC LYMPH NODE C1/VII

Source: NCI Genomic Data Commons file ba3e574b-82fc-4b11-8b7e-f1af705b8420 (TCGA-D5-5541.1A21E147-900C-4FAE-8A60-9A51093287F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).